Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A40G, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A40G-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code _____

Patient Age/Sex /

ICD-O-3

carcinoma, urothelial, NOS
8120/3

SPECIMEN SUBMITTED:

Part A: BLADDER AND PROSTATE

Sit: path: bladder, NOS C67.9

Part B: PELVIC LYMPH NODES #1

CACF: bladder, wall, NOS C67.9

Part C: PELVIC LYMPH NODES #2

Part D: RIGHT DISTAL URETER

7-5-12 RD

Final Diagnosis

1. Bladder and prostate, radical cystoprostatectomy (A) - Invasive high grade urothelial carcinoma is identified involving the previous biopsy site. The tumor focally invades into the muscularis propria. Associated urothelial carcinoma in situ is present.

- Right ureter margin is positive for urothelial carcinoma in-situ. The urethra margin and soft tissue margins are negative for tumor.

- The prostatic urethra shows involvement by urothelial carcinoma in situ. The prostate parenchyma shows benign prostatic hyperplasia.

- One lymph node negative for neoplasm (0/1).

- See comment.

2. Pelvic lymph nodes #1, excision (B) - Fifteen lymph nodes negative for neoplasm (0/15).

3. Pelvic lymph nodes #2, excision (C) - Three lymph nodes negative for neoplasm (0/3).

4. Right distal ureter, excision (D) Urothelial carcinoma in situ is present at the margin.

HPVAA Discrepancy		/

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

BLADDER TEMPLATE

Procedure:

Radical cystoprostatectomy

Tumor Size (greatest dimension): 5 cm (including previous biopsy site changes)

Histologic Type: Urothelial carcinoma

Associated Epithelial Lesions: None identified

Histologic grade:

Urothelial Carcinoma (WHO): High-grade

Adenocarcinoma and Squamous Carcinoma:

GX: Cannot be assessed

Margins:

Margin(s) involved by carcinoma in situ

Specify margin(s): right distal ureter

Venous lymphatic invasion: Absent

Direct extension of invasive tumor: None identified

Pathologic Stage (TNM): pT1 pN0 pMX

Number lymph nodes examined: 19

Number lymph nodes involved (any size): 0

Primary Tumor (pT)

pT2a: Tumor invades superficial muscularis propria (inner half).

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM):

pMX: Cannot be assessed

Seen in consultation with Dr.

Frozen section slides were reviewed on the re-excision of the right ureter. The cytologic atypia borders on dysplasia and urothelial carcinoma in situ, but review of the permanents favors urothelial carcinoma in situ.

Clinical Diagnosis:

BLADDER CANCER

STITCH MARKS MARGIN

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received already fixed, inked, and opened labeled "bladder and prostate" is a specimen that consists of urinary bladder, right ureter, prostate, attached seminal vesicles and vas deferens. The right ureter is probed but there is no probe identifying the left ureter and the left ureter orifice in the trigone area could not be seen or probed and after dissection a possible 3cm segment of left ureter is seen. The bladder measures 19 x 11 x 5 cm. The adhered surface of the bladder is covered by a smooth serosal lining at the dome and fibroadipose tissue at the remaining portion. After the bladder is opened, a mass measuring 5 x 4 x 1 cm is identified and is located on the anterior wall, right lateral wall, left lateral wall, posterior wall and the trigone area. The mass is 4 cm from the right ureter margin, 3.5 cm from the urethral margin, and 3.5 cm from the possible left ureter margin, and appears to invade 1 cm deep. The mass is principally papillary. On sectioning, the mass extends to roughly 1 cm grossly into the wall but does not grossly appear to go through the muscularis propria. It does not appear to involve the perivesicular adipose tissue. The bladder mucosa is erythematous near the urethra. A 4 cm segment of right ureter and is patent, and the mucosa appears unremarkable. The left ureter was very difficult to locate as there is no probe within it for fixation and the orifice in the trigone area could not be identified. A possible 3 cm segment of left ureter is identified after dissection. Its mucosa appears unremarkable. The prostate measures 4 x 4 x 4 cm craniocaudally, anteroposteriorly, and transversely. The apex of the gland is conical. The capsular surface is smooth. On palpation, an area of firmness is not identified. The gland is inked blue on the right, and yellow on the left. After fixation, the gland is serially sectioned at 3 mm intervals and the cross sections do not reveal a mass lesion. Rubbery nodularity is present. The seminal vesicles appear unremarkable. Representative sections are submitted as follows: FSA1 urethra, FSA2 suture, FSA3 left vas deferens, FSA4 right vas deferens, FSA5 right ureter, FSA6 left ureter, A8 anterior wall with mass, A9 right trigone area and right ureter with mass, A10 right lateral wall with mass, A11 dome, A12 left lateral wall with mass, A13 possible left ureter distal margin, A14 left trigone area with mass, A15 mass in relation to right seminal vesicle, A16 bladder mucosa near urethra, A17 posterior wall with mass, A18 possible mid left ureter, A19 right mid ureter, A20-A21 possible lymph nodes, A22 right apex, A23 left apex, A24 3 mm right, A25 3 mm left, A26 mid prostate right anterior, A27 mid prostate left anterior, A28 mid posterior right posterior, A29 mid prostate left posterior, A30 base of prostate right anterior, A31 base of prostate left anterior, A32 base of prostate right posterior, A33 base of prostate left posterior, A34 right seminal vesicle, A35 left seminal vesicle.

B. Received fresh labeled "pelvic lymph nodes #1" are multiple segments of yellow fibrofatty tissue aggregating to 10 x 5 x 1.5 cm. Palpation reveals 17 yellow firm nodules ranging in size from 0.5 to 4.0 cm in greatest dimension. The nodules are totally submitted as follows: B1 four nodules, B2 four nodules, B3 four nodules, B4 two nodules, B5 one nodule, B6 nodule, B7 one nodule bisected.

C. Received fresh labeled "pelvic lymph nodes #2" is a segment of yellow fibrofatty tissue measuring 7 x 4 x 1 cm. Palpation reveals 3 yellow firm nodules ranging in size from 3.0 to 5.0 cm in greatest dimension. The nodules are totally submitted as follows: C1 one nodule, C2-C3 one nodule bisected, C4-C5 one nodule bisected.

D. Received fresh for intraoperative consultation is a specimen labeled "right distal ureter" consisting of a segment of unoriented ureter, measuring 1.2 cm in length with a clip in place 0.4 cm from one end of

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

the ureter. The end of the ureter closest to the clip is inked black. The opposing ureter is dilated. Shaves of both ends of the ureter are submitted for frozen section in cassette FSD1.

Source: NCI Genomic Data Commons file 75c5eab9-7f13-4a49-a231-6cde6b3ad04c (TCGA-GV-A40G.28754343-DA2B-4608-A66C-B4E41B52F6FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).